Somatic mutation profile of tumor specimen MBCProject_3860_T1A_WES (aliquot MBCProject_3860_T1A_WES_1) from CMI case MBCProject_3860, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 66.9 years (24,442 days).
Specimen MBCProject_3860_T1A_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f06b0b1-04cd-4346-b2d7-1cf035517bad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_3860_SALIVA (Saliva), aliquot MBCProject_3860_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99757c6b-34b2-48c6-aaf3-8830dd0060e2

The open-access MAF lists 13 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, Nonsense Mutation 2, Missense Mutation 2, RNA 2, Translation Start Site 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AASDH | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 10/71 reads (14%) | catalogued as rs765349701, COSV52704659; called by muse, mutect2, varscan2
- ACSL3 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 7/23 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs1444491750; called by muse, mutect2, varscan2
- PCDHB9 | c.1432A>T p.R478* | Nonsense Mutation (SNP) | VAF 22/262 reads (8%) | catalogued as rs1554283111; called by muse, mutect2
- PKD2L1 | c.1081G>A p.V361I | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as rs1404081116, COSV58396568; called by muse, mutect2, varscan2
- FLT4 | c.1438C>G p.Q480E | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- TSSK6 | c.668dup p.Q224Pfs*? | Frame Shift Ins (INS) | VAF 5/39 reads (13%) | called by mutect2, pindel, varscan2
- ALX4 | c.1041C>T p.T347= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as rs766238204; ClinVar: likely benign; called by mutect2, varscan2
- TBCEL | c.183C>A p.T61= | Silent (SNP) | VAF 8/55 reads (15%) | called by muse, varscan2
- TICRR | c.5634A>G p.V1878= | Silent (SNP) | VAF 5/31 reads (16%) | called by muse, varscan2
- TMEM229B | c.267C>T p.F89= | Silent (SNP) | VAF 12/95 reads (13%) | called by muse, varscan2
- FAM205BP | n.1910C>T | RNA (SNP) | VAF 22/284 reads (8%) | catalogued as rs866343492; called by muse, mutect2
- TUBBP5 | n.1427C>T | RNA (SNP) | VAF 4/12 reads (33%) | catalogued as rs189844666; called by mutect2, varscan2
- ZNF880 | c.268+51A>T | Intron (SNP) | VAF 8/60 reads (13%) | called by muse, varscan2
